Somatic mutation profile of tumor specimen RC-B5D0-TBR1-A (aliquot RC-B5D0-TBR1-A-1-0-D-A93N-47) from RC case RC-B5D0, project RC-PTCL: Refractory Cancers (RC) - Peripheral T-Cell Lymphoma (PTCL). Sex at birth: male; Vital status: Dead; Primary diagnosis: Peripheral T-cell lymphoma, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 80.2 years (29,284 days).
Specimen RC-B5D0-TBR1-A: Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Peripheral Whole Blood; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 93624a06-e596-46e5-ab31-2766a22c15e0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen RC-B5D0-NB1-A (Granulocytes; tissue type Normal), aliquot RC-B5D0-NB1-A-1-0-D-A93N-47; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/abee609a-d7c0-4212-b82a-14648082c52c

The open-access MAF lists 12 somatic variants for this specimen: 8 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 8, Silent 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARHGEF10L | c.1010G>A p.R337Q | Missense Mutation (SNP) | VAF 50/114 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs770572310; called by mutect2, varscan2
- GPR27 | c.1001A>C p.N334T | Missense Mutation (SNP) | VAF 32/190 reads (17%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.995); catalogued as COSV55205958; called by mutect2, varscan2
- YBX1 | c.10G>A p.E4K | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.905); catalogued as rs1046707572; called by muse, varscan2
- DIAPH1 | c.3167A>G p.Q1056R | Missense Mutation (SNP) | VAF 36/76 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.017); called by mutect2, varscan2
- GABRG1 | c.542G>T p.R181I | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCARE | c.3400A>C p.K1134Q | Missense Mutation (SNP) | VAF 16/186 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.081); called by muse, mutect2
- SLC18A2 | c.145T>C p.Y49H | Missense Mutation (SNP) | VAF 43/103 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SORBS1 | c.16G>A p.D6N | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.367); called by muse, mutect2, varscan2
- BANK1 | c.720G>A p.R240= | Silent (SNP) | VAF 35/100 reads (35%) | catalogued as rs371674284; called by muse, mutect2, varscan2
- KRTAP9-1 | c.634C>T p.L212= | Silent (SNP) | VAF 21/157 reads (13%) | called by muse, mutect2, varscan2
- RPL34 | c.18A>C p.T6= | Silent (SNP) | VAF 14/80 reads (18%) | called by muse, mutect2
- SHROOM4 | c.18G>A p.G6= | Silent (SNP) | VAF 8/78 reads (10%) | called by muse, mutect2, varscan2
